Somatic mutation profile of tumor specimen TARGET-40-PAPNVD-01A (aliquot TARGET-40-PAPNVD-01A-01D) from TARGET case TARGET-40-PAPNVD, project TARGET-OS (Osteosarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 14.5 years (5,289 days).
Specimen TARGET-40-PAPNVD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6d5a26b1-212b-4f31-abce-93848cfef5ac.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-PAPNVD-10A (Blood Derived Normal), aliquot TARGET-40-PAPNVD-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b21b87dd-3658-4a81-8b5a-b65b0f80eb44

The open-access MAF lists 53 somatic variants for this specimen: 40 protein-altering or splice-affecting, 5 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 5, Nonsense Mutation 4, Intron 4, 5'UTR 2, 3'Flank 1, Frame Shift Del 1, RNA 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DMD | c.5563C>T p.Q1855* | Nonsense Mutation (SNP) | VAF 6/50 reads (12%) | catalogued as rs1569559097, CM096757; ClinVar: pathogenic; called by muse, mutect2
- MYH7 | c.2572C>T p.R858C | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as rs2754158, CM042415, CM135610, CM1413734; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS5 | c.707C>T p.S236L | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs1486887134, COSV53185262; called by muse, mutect2
- ARHGAP15 | c.1277C>G p.S426C | Missense Mutation (SNP) | VAF 25/166 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV99710319; called by muse, mutect2, varscan2
- CAND1 | c.292G>A p.D98N | Missense Mutation (SNP) | VAF 10/153 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.055); catalogued as COSV73338555, COSV73338677; called by muse, mutect2
- CNTNAP5 | c.607G>A p.D203N | Missense Mutation (SNP) | VAF 21/188 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.346); catalogued as COSV70484487; called by muse, mutect2, varscan2
- ELMO2 | c.1712G>A p.R571Q | Missense Mutation (SNP) | VAF 113/197 reads (57%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.884); catalogued as rs1454354899; called by muse, mutect2, varscan2
- FCRLA | c.25G>T p.V9F | Missense Mutation (SNP) | VAF 8/158 reads (5%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.013); catalogued as COSV52686557; called by muse, mutect2
- GORASP2 | c.719A>T p.N240I | Missense Mutation (SNP) | VAF 14/138 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.115); catalogued as COSV52203396; called by muse, mutect2
- GRM7 | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.114); catalogued as COSV63168544; called by mutect2, varscan2
- IHH | c.1060C>A p.H354N | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.239); catalogued as COSV55393839; called by muse, mutect2, varscan2
- PDE4DIP | c.2330C>G p.S777C | Missense Mutation (SNP) | VAF 12/256 reads (5%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.959); catalogued as rs1553538868; called by muse, mutect2
- PDLIM3 | c.478C>T p.L160F (on ENST00000284770 / NM_001257963.1; = p.L327F on NM_014476.6) | Missense Mutation (SNP) | VAF 8/204 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52979282; called by muse, mutect2
- PTPRH | c.2128T>C p.S710P | Missense Mutation (SNP) | VAF 21/162 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.132); catalogued as rs146115875; called by muse, mutect2, varscan2
- STAG1 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.473); catalogued as rs1321480173, COSV52626117; called by muse, mutect2, varscan2
- TP53AIP1 | c.334C>G p.L112V | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.519); catalogued as rs1565329138; called by muse, mutect2, varscan2
- ZIC2 | c.1016G>T p.G339V | Missense Mutation (SNP) | VAF 82/206 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775296747, COSV100891803; called by muse, mutect2, varscan2
- ABHD3 | c.791G>A p.W264* | Nonsense Mutation (SNP) | VAF 45/117 reads (38%) | called by muse, mutect2, varscan2
- AHNAK | c.7051C>A p.P2351T | Missense Mutation (SNP) | VAF 22/302 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ATF7IP | c.1516G>C p.D506H | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- DGKE | c.173G>C p.S58T | Missense Mutation (SNP) | VAF 22/156 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- EIF4G3 | c.2995A>G p.I999V | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- ENC1 | c.456G>A p.M152I | Missense Mutation (SNP) | VAF 131/179 reads (73%) | SIFT tolerated (0.7); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- F12 | c.1512_1515del p.W505Afs*158 | Frame Shift Del (DEL) | VAF 56/86 reads (65%) | called by mutect2, pindel, varscan2
- FAT1 | c.7864G>A p.D2622N | Missense Mutation (SNP) | VAF 20/331 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FLT1 | c.3013C>A p.Q1005K | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- GTF2H2C | c.400G>C p.A134P | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.916); called by muse, mutect2
- INPP4B | c.782C>G p.S261C | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- LTBP1 | c.1786A>T p.K596* (on ENST00000404816 / NM_206943.4; = p.K270* on NM_000627.4) | Nonsense Mutation (SNP) | VAF 14/73 reads (19%) | called by muse, mutect2, varscan2
- MEGF8 | c.1519G>C p.A507P | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- MUC16 | c.28489G>T p.D9497Y | Missense Mutation (SNP) | VAF 51/302 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- NME4 | c.104G>A p.W35* | Nonsense Mutation (SNP) | VAF 15/53 reads (28%) | called by muse, mutect2, varscan2
- OR2L13 | c.866A>G p.Y289C | Missense Mutation (SNP) | VAF 14/180 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- OR5F1 | c.479C>T p.T160I | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RC3H2 | c.137A>T p.H46L | Missense Mutation (SNP) | VAF 7/120 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.888); called by muse, mutect2
- RNF6 | c.1777T>G p.L593V | Missense Mutation (SNP) | VAF 16/178 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.33); called by muse, mutect2
- SLITRK3 | c.2159G>T p.G720V | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.2); called by muse, mutect2, varscan2
- TBX5 | c.265G>C p.V89L | Missense Mutation (SNP) | VAF 82/193 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.636); called by muse, mutect2, varscan2
- UBR3 | c.3743A>T p.D1248V | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.211); called by muse, mutect2, varscan2
- ZACN | c.502_510del p.H168_N170del | In Frame Del (DEL) | VAF 21/176 reads (12%) | called by mutect2, pindel, varscan2
- ADORA3 | c.84G>A p.V28= | Silent (SNP) | VAF 34/97 reads (35%) | called by muse, mutect2, varscan2
- CNPPD1 | c.594G>C p.R198= | Silent (SNP) | VAF 8/138 reads (6%) | called by muse, mutect2
- FMR1 | c.729A>G p.Q243= | Silent (SNP) | VAF 37/150 reads (25%) | called by muse, mutect2, varscan2
- GNL3 | c.1443G>A p.Q481= | Silent (SNP) | VAF 14/77 reads (18%) | called by muse, mutect2, varscan2
- SETDB2 | c.1272T>C p.N424= | Silent (SNP) | VAF 27/81 reads (33%) | called by muse, mutect2, varscan2
- AHRR | c.971-66C>T | Intron (SNP) | VAF 35/100 reads (35%) | called by muse, mutect2, varscan2
- LYNX1 | c.-65G>C | 5'UTR (SNP) | VAF 16/33 reads (48%) | called by muse, mutect2, varscan2
- NIPBL | c.8049+19C>G | Intron (SNP) | VAF 12/79 reads (15%) | called by muse, mutect2, varscan2
- OR13H1 | c.-81C>T | 5'UTR (SNP) | VAF 4/49 reads (8%) | called by muse, mutect2
- OR52K3P | n.1162G>C | RNA (SNP) | VAF 16/93 reads (17%) | called by muse, mutect2, varscan2
- PDE1A | c.-10-11T>C | Intron (SNP) | VAF 76/114 reads (67%) | catalogued as COSV100116514; called by muse, mutect2
- SFTPC | c.*18+49C>T | Intron (SNP) | VAF 4/24 reads (17%) | called by muse, mutect2, varscan2
- USP34 | chr2:61186174 C>G | 3'Flank (SNP) | VAF 13/130 reads (10%) | called by muse, mutect2
